Gene-level copy-number profile of tumor specimen TCGA-D3-A8GC-06A from TCGA case TCGA-D3-A8GC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.2 years (19,418 days).
Specimen TCGA-D3-A8GC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.1c25d230-467d-46ea-964e-36a3d62e4068.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A8GC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d7b730b-8cb7-444c-90d8-05a85a5befbb

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 315; copy number 3: 17,748; copy number 4: 7,334; copy number 5: 13,229; copy number 6: 18,299; copy number 7: 941; copy number 8: 8; copy number 9: 188; copy number 10: 108; copy number 11: 623; copy number 12: 958; copy number 13: 42; copy number 14: 4; copy number 16: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A8GC-06A-11D-A371-01): tumor purity 0.81, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:96,310,701–96,818,864, 1 gene (within-gene range 0–3): LINC02267.
- chr4:96,841,995–96,903,050, 2 genes: AC096585.1, COX7A2P2.
- chr11:80,321,620–80,528,066, 2 genes: AP006295.1, RNU6-544P.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 58 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:57,512,181–57,863,053, 15 genes, copy number 13–14: CCDC102A, ADGRG5, HMGB3P32, ADGRG1, AC018552.3, ADGRG3, AC018552.2, DRC7, AC018552.1, KATNB1, KIFC3, AC092118.2, MIR6772, AC092118.1, RNU6-20P.
- chr16:59,709,993–60,053,973, 3 genes, copy number 14: APOOP5, LINC02141, AC009094.1.
- chr16:72,112,157–72,665,014, 6 genes, copy number 16 (within-gene range 9–16): PMFBP1, AC009075.1, LINC01572, AC009075.2, U6, AC004158.1.
- chr16:74,999,024–75,556,268, 27 genes, copy number 13: ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231.
- chr16:75,556,392–75,557,059, 1 gene, copy number 13: AC025287.2.
- chr16:77,788,564–77,980,107, 1 gene, copy number 16 (within-gene range 9–16): VAT1L.
- chr16:77,892,422–78,066,761, 5 genes, copy number 16: PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
